Somatic mutation profile of tumor specimen MMRF_2180_1_BM_CD138pos (aliquot MMRF_2180_1_BM_CD138pos_T1_KHS5U_L08705) from MMRF case MMRF_2180, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.2 years (21,977 days).
Specimen MMRF_2180_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 467f3f0f-66a5-4d59-93b5-86179ced2ae2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2180_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2180_1_PB_Whole_C3_KHS5U_L08704; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f27954e8-a3cc-4277-a1a0-396ed2a5f801

The open-access MAF lists 78 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 23, Silent 9, Intron 8, 5'UTR 2, 3'Flank 2, 5'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs780220308; called by muse, mutect2, varscan2
- BFSP2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs141155612, COSV100183465; called by muse, mutect2, varscan2
- CLDN25 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs749373712; called by muse, mutect2, varscan2
- CSMD1 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 78/148 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as rs1439328686; called by muse, mutect2, varscan2
- DDX23 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1418397334, COSV57284916, COSV57286745; called by muse, mutect2, varscan2
- FLRT3 | c.1910G>A p.R637K | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.288); catalogued as COSV99446085; called by muse, mutect2, varscan2
- GIMAP1 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as rs929536980, COSV56189652; called by muse, mutect2, varscan2
- IGF2R | c.2347C>A p.L783M | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63630506; called by muse, mutect2
- IGHJ2 | c.7T>G p.Y3D | Missense Mutation (SNP) | VAF 48/50 reads (96%) | PolyPhen benign (0.003); catalogued as rs372771442; called by muse, mutect2, varscan2
- IGLV1-47 | c.240C>G p.D80E | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs763680907; called by muse, varscan2
- KIAA1217 | c.2108A>G p.Q703R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1441321196; called by muse, mutect2, varscan2
- TNXB | c.7220A>G p.K2407R (on ENST00000647633; = p.K2160R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs779563644; called by muse, mutect2
- TTN | c.70512G>C p.W23504C (on ENST00000591111; = p.W16080C on NM_003319.4) | Missense Mutation (SNP) | VAF 43/165 reads (26%) | PolyPhen probably damaging (0.999); catalogued as rs879003453; called by muse, mutect2, varscan2
- ZIC3 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV54977654; called by muse, mutect2, varscan2
- ARMH3 | c.576T>G p.I192M | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CDH19 | c.195+1G>C p.X65_splice | Splice Site (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- CEP295 | c.5911A>C p.S1971R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHRNA2 | c.1401G>C p.Q467H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- CTAGE1 | c.533T>C p.I178T | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DCLRE1A | c.2395A>C p.M799L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- GOLPH3L | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGI1 | c.3734G>T p.S1245I | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- MYH14 | c.3884C>A p.A1295D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- MYOCD | c.117A>G p.I39M | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OAZ1 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PATJ | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2
- SNX33 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPC4 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- TUT7 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UCHL5 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF717 | c.2230G>T p.V744F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.125); called by muse, varscan2
- ZNF805 | c.1700T>G p.I567S | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BMP15 | c.987C>T p.R329= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as rs782003640; called by muse, mutect2, varscan2
- ELOA | c.1545C>T p.P515= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs535890865; called by muse, mutect2, varscan2
- F2 | c.696C>A p.L232= | Silent (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- RFX4 | c.864G>A p.K288= (on ENST00000392842 / NM_213594.3; = p.K194= on NM_032491.6) | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV57581739; called by muse, mutect2, varscan2
- RIPOR3 | c.1491C>T p.H497= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs545997871, COSV50385519; called by muse, mutect2, varscan2
- ROBO2 | c.870C>A p.T290= | Silent (SNP) | VAF 25/194 reads (13%) | called by muse, mutect2, varscan2
- RTBDN | c.330G>A p.Q110= (on ENST00000393233 / NM_001270444.1; = p.Q142= on NM_031429.2) | Silent (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- SUSD1 | c.1971A>G p.L657= | Silent (SNP) | VAF 82/219 reads (37%) | catalogued as rs201523589; called by muse, mutect2, varscan2
- TEK | c.15C>T p.A5= | Silent (SNP) | VAF 24/451 reads (5%) | catalogued as rs915202645; called by muse, mutect2
- ACSM5P1 | n.1156G>A | RNA (SNP) | VAF 29/102 reads (28%) | catalogued as rs946293408; called by muse, mutect2, varscan2
- ARHGAP6 | c.2176+208C>A | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100272899; called by muse, mutect2, varscan2
- BBS1 | c.1340-354G>C | Intron (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- C3orf70 | c.*2615G>A | 3'UTR (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- CASTOR2 | c.*224C>T | 3'UTR (SNP) | VAF 14/24 reads (58%) | catalogued as rs1173835360; called by muse, mutect2, varscan2
- CFL2 | c.*1673C>A | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- CTSB | chr8:11843442 C>T | 3'Flank (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- GDPD1 | c.367+57C>A | Intron (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- GPR63 | c.-79G>T | 5'UTR (SNP) | VAF 65/174 reads (37%) | catalogued as COSV100013530; called by muse, mutect2, varscan2
- GPT2 | c.*615G>C | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- GRB2 | c.*1023C>G | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- GRIN2A | c.*6424T>C | 3'UTR (SNP) | VAF 20/39 reads (51%) | catalogued as rs771240791; called by muse, mutect2, varscan2
- HFE | c.*3597T>G | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- HHIPL1 | c.*3672T>C | 3'UTR (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- HOXA3 | c.*723C>T | 3'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- KHDRBS3 | c.*291T>C | 3'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- MED20 | c.*23C>A | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851176 G>A | 5'Flank (SNP) | VAF 81/158 reads (51%) | catalogued as rs544903906; called by muse, mutect2, varscan2
- MYO3B | c.3734-4718C>T | Intron (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- NEDD9 | c.*858G>T | 3'UTR (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- NHLH2 | c.-9+779G>A | Intron (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- NTRK3 | c.*11445C>T | 3'UTR (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- PTPRN2 | c.*1437C>T | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- SELENOI | c.*1000C>G | 3'UTR (SNP) | VAF 55/121 reads (45%) | called by muse, mutect2, varscan2
- SOHLH2 | c.641+7085T>G | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- THEMIS | c.*557C>T | 3'UTR (SNP) | VAF 9/46 reads (20%) | catalogued as rs1476744339; called by muse, mutect2, varscan2
- THSD7A | c.*981T>A | 3'UTR (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- TLN2 | c.5736+820A>T | Intron (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- TMEM167A | c.*3363G>T | 3'UTR (SNP) | VAF 54/249 reads (22%) | called by muse, mutect2, varscan2
- TMEM260 | c.*1913G>A | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- TMEM37 | c.*576A>G | 3'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- TMEM39A | c.*729A>T | 3'UTR (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2
- TSPEAR | c.1566+1825G>A | Intron (SNP) | VAF 84/427 reads (20%) | catalogued as rs948765722; called by muse, mutect2, varscan2
- UBE2A | c.-52C>T | 5'UTR (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- WIPF2 | c.*4459A>G | 3'UTR (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- ZNF462 | c.*2162T>C | 3'UTR (SNP) | VAF 10/94 reads (11%) | catalogued as rs903886032; called by muse, mutect2
- ZNF780A | chr19:40071368 A>G | 3'Flank (SNP) | VAF 61/88 reads (69%) | called by muse, mutect2, varscan2
